Somatic mutation profile of tumor specimen TCGA-EJ-7785-01A (aliquot TCGA-EJ-7785-01A-11D-2114-08) from TCGA case TCGA-EJ-7785, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.6 years (19,939 days).
Specimen TCGA-EJ-7785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 377f4995-f09d-4091-a01a-bd4f73b4a576.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7785-10A (Blood Derived Normal), aliquot TCGA-EJ-7785-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7236bb1a-4379-4b69-9bc2-04d16bd3da79

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.8596G>A p.A2866T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV54959503; called by muse, mutect2
- CCDC66 | c.1343T>A p.L448H (on ENST00000394672 / NM_001353147.1; = p.L414H on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58310266; called by muse, mutect2, varscan2
- CLTC | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.046); catalogued as rs1165273019, COSV52245514, COSV52253641; called by muse, mutect2, varscan2
- CRYBB3 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs781479810, COSV53195601; called by muse, mutect2, varscan2
- CYP19A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747006734, COSV53061986; called by muse, mutect2, varscan2
- EIF4G3 | c.2454G>C p.T818= | Splice Region (SNP) | VAF 16/88 reads (18%) | catalogued as COSV51679669, COSV51695427; called by muse, varscan2
- FAM8A1 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52583507; called by muse, mutect2, varscan2
- GEMIN7 | c.16A>G p.N6D | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54320882; called by muse, mutect2, varscan2
- KDR | c.3911G>A p.G1304D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.384); catalogued as COSV55777639; called by muse, mutect2
- LAMB1 | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV55970876; called by muse, mutect2
- PDE6C | c.1877G>C p.G626A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV65117949; called by muse, mutect2, varscan2
- SPTBN5 | c.5500C>T p.R1834* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs377166485; called by muse, mutect2, varscan2
- WDR37 | c.1057A>G p.R353G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99580267; called by muse, mutect2
- ZIC5 | c.1649C>G p.P550R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57439146; called by muse, mutect2, varscan2
- ZNF142 | c.4280G>A p.R1427H (on ENST00000411696 / NM_001379660.1; = p.R1227H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs778416781, COSV101377033, COSV68745368; called by muse, mutect2, varscan2
- TMEM132E | c.1090del p.A364Pfs*3 (on ENST00000321639; = p.A454Pfs*3 on NM_001304438.2) | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.2004G>A p.V668= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as COSV59461193; called by muse, mutect2, varscan2
- LAMA2 | c.8385C>T p.T2795= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs142445491, COSV70339646; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC17 | c.6804C>T p.S2268= | Silent (SNP) | VAF 44/328 reads (13%) | catalogued as COSV60305641; called by muse, mutect2, varscan2
- NCDN | c.1455G>T p.G485= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs771863772, COSV61937418; called by muse, mutect2, varscan2
- SSX5 | c.126C>T p.A42= (on ENST00000347757 / NM_175723.1; = p.A83= on NM_021015.4) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61256627; called by muse, mutect2, varscan2
